Somatic mutation profile of tumor specimen 0DDA74 from CCDI case PBBJWM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, benign; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,546 days).
Specimen 0DDA74: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11b11f2f-2d5f-4aa0-9d57-efab42b1ed1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDA6Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19c5346b-6f48-44c4-be70-b9fc1607d7ce

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2C1 | c.920C>G p.P307R | Missense Mutation (SNP) | VAF 175/701 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM077232, CM1414392; called by muse, mutect2, varscan2
- MAGEB4 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 266/948 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1422732466, COSV64397289; called by muse, mutect2, varscan2
- PCDHB11 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 156/1151 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1554285402, COSV61310690; called by muse, mutect2, varscan2
- MACF1 | c.11850G>T p.L3950F (on ENST00000372915; = p.L1883F on NM_012090.5) | Missense Mutation (SNP) | VAF 31/890 reads (3%) | called by muse, mutect2
- OBSCN | c.5711G>A p.G1904E | Missense Mutation (SNP) | VAF 31/720 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2
- WWC3 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 202/621 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- GNL3 | c.766C>A p.R256= | Silent (SNP) | VAF 249/699 reads (36%) | catalogued as rs903502136; called by muse, mutect2, varscan2
- RTEL1 | c.3426C>A p.G1142= | Silent (SNP) | VAF 288/1260 reads (23%) | called by muse, mutect2, varscan2
- RTL8B | c.222G>A p.G74= | Silent (SNP) | VAF 36/774 reads (5%) | called by muse, mutect2
